Somatic mutation profile of cancer-model specimen HCM-CSHL-0606-C17-85A (3D Organoid, passage 6; aliquot HCM-CSHL-0606-C17-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0606-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 71.6 years (26,157 days).
Specimen HCM-CSHL-0606-C17-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b53b50e-ba27-4513-ba8a-fe29c1834c51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0606-C17-11B (Solid Tissue Normal), aliquot HCM-CSHL-0606-C17-11B-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cc013e6-bba8-4802-9633-c595f8c419f3

The open-access MAF lists 2,383 somatic variants for this specimen: 1,743 protein-altering or splice-affecting, 548 silent, 92 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,291, Silent 548, Frame Shift Del 306, Intron 56, Frame Shift Ins 55, Nonsense Mutation 53, 3'UTR 18, Splice Site 15, Splice Region 13, 5'UTR 6, 3'Flank 6, 5'Flank 4.

Variants (750 of 2,383; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 112/271 reads (41%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC2 | c.3216dup p.D1073* | Frame Shift Ins (INS) | VAF 171/427 reads (40%) | catalogued as rs771652807; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BTD | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 190/449 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs397514381, CM163096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ELANE | c.561C>A p.C187* | Nonsense Mutation (SNP) | VAF 380/745 reads (51%) | catalogued as rs797045009, CM078262; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.506del p.G169Afs*23 | Frame Shift Del (DEL) | VAF 173/413 reads (42%) | catalogued as rs1452295073; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNQ2 | c.1229del p.P410Rfs*30 (on ENST00000359125 / NM_172107.4; = p.P400Rfs*12 on NM_004518.6) | Frame Shift Del (DEL) | VAF 260/685 reads (38%) | catalogued as rs886041339, CD094786; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 177/350 reads (51%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 100/182 reads (55%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MAF | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 426/820 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs727502766, CM154008; ClinVar: pathogenic; called by muse, varscan2
- MYO7A | c.3572G>A p.G1191D | Missense Mutation (SNP) | VAF 256/514 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516301, COSV68685727; ClinVar: likely pathogenic; called by muse, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 100/193 reads (52%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PROM1 | c.1354dup p.Y452Lfs*13 | Frame Shift Ins (INS) | VAF 208/434 reads (48%) | catalogued as rs543698823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- RYR1 | c.3801del p.C1268Afs*4 | Frame Shift Del (DEL) | VAF 253/621 reads (41%) | catalogued as rs587784374; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RYR1 | c.7360C>T p.R2454C | Missense Mutation (SNP) | VAF 195/452 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs193922816, CM992215; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TACR3 | c.737+1G>A p.X246_splice | Splice Site (SNP) | VAF 101/218 reads (46%) | catalogued as rs760022956, CS104228, COSV59199949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.4262del p.G1421Afs*23 | Frame Shift Del (DEL) | VAF 246/567 reads (43%) | catalogued as rs768628795; called by mutect2, pindel, varscan2
- ABCC10 | c.1046A>G p.Y349C (on ENST00000372530 / NM_001198934.2; = p.Y306C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/669 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1400513910; called by muse, mutect2
- ABCC12 | c.1918C>T p.H640Y | Missense Mutation (SNP) | VAF 239/462 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV60915187; called by muse, mutect2, varscan2
- ABCC2 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs747591710; called by muse, mutect2, varscan2
- ABCC8 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV56847793; called by muse, mutect2
- ABCG8 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 130/322 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.153); catalogued as rs1188356143; called by muse, mutect2
- ACACB | c.7190C>A p.S2397Y | Missense Mutation (SNP) | VAF 60/666 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368703551; called by muse, mutect2
- ACAD10 | c.305del p.L102Yfs*12 | Frame Shift Del (DEL) | VAF 166/424 reads (39%) | catalogued as rs1266702641; called by mutect2, pindel, varscan2
- ACTC1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 154/341 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs1179943060, COSV51757242, COSV51759304; called by muse, mutect2, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 106/513 reads (21%) | catalogued as rs751325833; called by pindel, varscan2
- ACTL7B | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 327/699 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as rs767348925, COSV101012603; called by muse, mutect2, varscan2
- ADAMTS7 | c.4345G>A p.A1449T | Missense Mutation (SNP) | VAF 386/833 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs1474758036; called by muse, mutect2, varscan2
- ADAMTSL1 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs368670565; called by muse, mutect2, varscan2
- ADAR | c.3603del p.G1202Afs*2 | Frame Shift Del (DEL) | VAF 235/541 reads (43%) | catalogued as CD052083; called by mutect2, pindel, varscan2
- ADGRB1 | c.2869G>A p.V957M | Missense Mutation (SNP) | VAF 72/1246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs775749064, COSV60092069; called by muse, mutect2
- ADGRG3 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 238/486 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs376154437, COSV59650277, COSV59651601; called by muse, mutect2, varscan2
- ADGRG4 | c.9100G>C p.E3034Q | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV54954588; called by muse, mutect2, varscan2
- ADM2 | c.299G>T p.R100M | Missense Mutation (SNP) | VAF 421/821 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99326733; called by muse, mutect2, varscan2
- ADPRHL1 | c.4514A>G p.Q1505R | Missense Mutation (SNP) | VAF 23/790 reads (3%) | SIFT tolerated, low confidence (0.07); catalogued as rs1007680226; called by muse, mutect2
- AGMAT | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 360/752 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs1188948300; called by muse, mutect2, varscan2
- AGRN | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 250/524 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1224886218; called by muse, varscan2
- AHNAK2 | c.5273G>A p.G1758D | Missense Mutation (SNP) | VAF 210/495 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373060297; called by muse, mutect2, varscan2
- AKAP11 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 177/328 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV99078672, COSV99213699; called by muse, mutect2, varscan2
- AKAP13 | c.2929G>A p.A977T | Missense Mutation (SNP) | VAF 148/330 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.82); catalogued as rs777734057, COSV63464018; called by muse, mutect2, varscan2
- AKAP6 | c.6238G>A p.E2080K | Missense Mutation (SNP) | VAF 170/381 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766419719, COSV55213312; called by muse, mutect2, varscan2
- AKAP8L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 334/699 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.915); catalogued as rs1192777344; called by muse, mutect2, varscan2
- ALG12 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 307/610 reads (50%) | PolyPhen possibly damaging (0.894); catalogued as rs774052738; called by muse, mutect2, varscan2
- ALG12 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 243/502 reads (48%) | PolyPhen benign (0.277); catalogued as rs761301009, COSV58206542; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2750C>A p.P917Q | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); catalogued as COSV99784583; called by muse, mutect2, varscan2
- ANKS6 | c.1948G>A p.G650S | Missense Mutation (SNP) | VAF 160/375 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.349); catalogued as rs761981516, COSV62052752; called by muse, mutect2, varscan2
- ANO6 | c.1081A>G p.N361D | Missense Mutation (SNP) | VAF 109/242 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs769324200; called by muse, mutect2, varscan2
- ANP32E | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58482962; called by muse, mutect2, varscan2
- ANXA6 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 147/348 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768920594; called by muse, mutect2, varscan2
- ANXA7 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs779036745; called by muse, mutect2, varscan2
- AP3M2 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1425052771, COSV99441377; called by muse, mutect2, varscan2
- AP4B1 | c.1432A>G p.T478A | Missense Mutation (SNP) | VAF 241/495 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs764646631; called by muse, mutect2, varscan2
- APBA2 | c.1039A>G p.K347E | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs893567577; called by muse, mutect2, varscan2
- APC | c.8042C>T p.P2681L | Missense Mutation (SNP) | VAF 184/397 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs182456139; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- APOB | c.9221A>G p.Y3074C | Missense Mutation (SNP) | VAF 178/389 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372902533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3D | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 134/293 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs1272069972; called by muse, mutect2, varscan2
- AR | c.170_178del p.L57_Q59del | In Frame Del (DEL) | VAF 69/224 reads (31%) | catalogued as rs766952703; called by pindel, varscan2
- AR | c.2407del p.Q803Rfs*6 | Frame Shift Del (DEL) | VAF 227/321 reads (71%) | catalogued as CM032832; called by mutect2, pindel, varscan2
- ARAF | c.619del p.L207Yfs*85 | Frame Shift Del (DEL) | VAF 33/360 reads (9%) | catalogued as COSV51695741; called by pindel, varscan2
- ARAP1 | c.1433T>C p.I478T (on ENST00000393609 / NM_001040118.2; = p.I233T on NM_015242.4) | Missense Mutation (SNP) | VAF 19/445 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1266606483; called by muse, mutect2
- ARAP3 | c.3197C>T p.T1066M | Missense Mutation (SNP) | VAF 274/589 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367852994; called by muse, mutect2, varscan2
- ARF5 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 151/319 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs1222389800; called by muse, mutect2, varscan2
- ARHGAP21 | c.5063G>A p.R1688Q | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs542841578; called by muse, mutect2, varscan2
- ARHGAP24 | c.2104C>T p.R702* (on ENST00000395184 / NM_001025616.3; = p.R609* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 158/284 reads (56%) | catalogued as rs376118883; called by muse, mutect2, varscan2
- ARHGAP32 | c.6217G>A p.A2073T (on ENST00000310343 / NM_001378025.1; = p.A1724T on NM_014715.4) | Missense Mutation (SNP) | VAF 188/374 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777247242; called by muse, mutect2, varscan2
- ARHGAP32 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs377461049; called by muse, mutect2, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 208/425 reads (49%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ARHGAP39 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 343/1455 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs756710619; called by muse, mutect2, varscan2
- ARHGAP39 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 418/1722 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1208122246; called by muse, varscan2
- ARHGEF3 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 43/543 reads (8%) | catalogued as COSV56332408; called by muse, mutect2
- ARID1A | c.6694C>T p.R2232W | Missense Mutation (SNP) | VAF 54/947 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61374953, COSV61383222; called by muse, mutect2
- ARPC5 | c.188del p.P63Lfs*9 | Frame Shift Del (DEL) | VAF 140/367 reads (38%) | catalogued as rs1558122795, COSV54172267; called by mutect2, pindel, varscan2
- ASH1L | c.5425A>G p.K1809E | Missense Mutation (SNP) | VAF 175/338 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as rs749856698; called by muse, mutect2, varscan2
- ASIC5 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 153/364 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs752632438, COSV73332561, COSV73332754; called by muse, mutect2, varscan2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 80/150 reads (53%) | catalogued as rs747712363; called by mutect2, varscan2
- ATF7IP | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 278/525 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1409123142, COSV53778159; called by muse, mutect2, varscan2
- ATP10A | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 239/436 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487739128, COSV63514924; called by muse, mutect2, varscan2
- ATP10B | c.2428A>G p.N810D | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV59163455; called by muse, mutect2, varscan2
- ATP13A1 | c.2605G>A p.V869M | Missense Mutation (SNP) | VAF 215/471 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1476114692, COSV52284385; called by muse, mutect2, varscan2
- ATP1A3 | c.619C>T p.R207W (on ENST00000545399 / NM_001256214.2; = p.R194W on NM_152296.5) | Missense Mutation (SNP) | VAF 268/562 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246646193, COSV57490638; called by muse, mutect2, varscan2
- ATP1A4 | c.69del p.I26Sfs*6 | Frame Shift Del (DEL) | VAF 191/456 reads (42%) | catalogued as rs1467294583; called by mutect2, pindel, varscan2
- ATXN2L | c.3004del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 192/543 reads (35%) | catalogued as rs771612620; called by pindel, varscan2
- ATXN2L | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 310/652 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.047); catalogued as rs1180893425, COSV57370240; called by muse, varscan2
- AVEN | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 222/452 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs564664081; called by muse, mutect2, varscan2
- AXIN2 | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 340/698 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100196918; called by muse, mutect2, varscan2
- AXL | c.2066C>T p.A689V (on ENST00000301178 / NM_021913.5; = p.A680V on NM_001699.6) | Missense Mutation (SNP) | VAF 167/370 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1420547997, COSV56565709; called by muse, varscan2
- AZU1 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 36/996 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV52142877; called by muse, mutect2
- B3GNTL1 | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 258/542 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs1350009199; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 158/354 reads (45%) | catalogued as rs35951843; called by mutect2, varscan2
- B4GALT7 | c.482T>C p.M161T | Missense Mutation (SNP) | VAF 265/520 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50353291; called by muse, mutect2, varscan2
- BACH1 | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 30/477 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54518516; called by muse, mutect2
- BAG5 | c.974dup p.N325Kfs*23 | Frame Shift Ins (INS) | VAF 121/253 reads (48%) | catalogued as rs1002009532; called by mutect2, varscan2
- BAP1 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 348/677 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs770422186, COSV56240811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 154/347 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563402885; called by muse, mutect2, varscan2
- BAZ2A | c.4934G>A p.R1645H | Missense Mutation (SNP) | VAF 234/471 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs756116591; called by muse, mutect2, varscan2
- BCL11A | c.1213G>A p.D405N (on ENST00000335712 / NM_001365609.1; = p.D439N on NM_018014.4) | Missense Mutation (SNP) | VAF 359/728 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV59637761; called by muse, mutect2, varscan2
- BIRC6 | c.4558G>A p.V1520I | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1289046338; called by muse, mutect2, varscan2
- BMPER | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs371676663; called by muse, mutect2, varscan2
- BOD1L1 | c.2693G>A p.R898Q | Missense Mutation (SNP) | VAF 109/293 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs375541900, COSV50014131; called by muse, mutect2, varscan2
- BRD2 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 213/504 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV66373847; called by muse, mutect2, varscan2
- BRINP2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 344/692 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.272); catalogued as COSV64177965; called by muse, mutect2, varscan2
- C14orf119 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 234/481 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs756125770; called by muse, mutect2, varscan2
- C1QTNF9 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 85/566 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1419089027; called by muse, mutect2, varscan2
- C2CD3 | c.2795A>G p.Y932C | Missense Mutation (SNP) | VAF 212/448 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58101219; called by muse, mutect2, varscan2
- C2CD4B | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 548/1042 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1396446421; called by muse, mutect2, varscan2
- C2orf16 | c.2970del p.M991Cfs*35 | Frame Shift Del (DEL) | VAF 115/288 reads (40%) | catalogued as COSV71613850; called by mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 143/290 reads (49%) | catalogued as rs747496393; called by mutect2, varscan2
- C2orf74 | c.107del p.L36Yfs*25 | Frame Shift Del (DEL) | VAF 88/204 reads (43%) | catalogued as rs1265298443; called by mutect2, pindel, varscan2
- C4orf54 | c.2182A>G p.I728V | Missense Mutation (SNP) | VAF 33/412 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.282); catalogued as rs745476750; called by muse, mutect2
- C6orf132 | c.3122C>T p.A1041V | Missense Mutation (SNP) | VAF 399/770 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1401584601; called by muse, mutect2, varscan2
- CAMKMT | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 94/200 reads (47%) | catalogued as rs777039644; called by muse, mutect2, varscan2
- CARS1 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 355/752 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461372759, COSV53453285; called by muse, mutect2, varscan2
- CASK | c.1133A>C p.Q378P | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.121); catalogued as COSV59375773; called by muse, mutect2, varscan2
- CBFA2T2 | c.1321del p.T441Qfs*5 | Frame Shift Del (DEL) | VAF 89/243 reads (37%) | catalogued as COSV100656585; called by pindel, varscan2
- CBFA2T3 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 273/606 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs751448990, COSV51925070; called by muse, mutect2, varscan2
- CCDC137 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs779033426, COSV61303499; called by muse, mutect2, varscan2
- CCDC138 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV54566844; called by muse, mutect2, varscan2
- CCDC158 | c.2870G>T p.R957I | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.203); catalogued as COSV66357336; called by muse, mutect2
- CCDC40 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 274/605 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1334974401; called by muse, mutect2, varscan2
- CCKAR | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 42/528 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV99810533; called by muse, mutect2
- CCNC | c.132del p.F44Lfs*8 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs1456359224; called by mutect2, pindel, varscan2
- CCND2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 295/609 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs776036883, COSV54225096; called by muse, mutect2, varscan2
- CD276 | c.1295C>T p.A432V (on ENST00000318443 / NM_001024736.2; = p.A214V on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 380/727 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs775977755, COSV59204592; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 69/464 reads (15%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD8B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 305/672 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.132); catalogued as rs1202642059; called by muse, mutect2, varscan2
- CDH1 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 230/491 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55737034; called by muse, mutect2, varscan2
- CDH10 | c.1883T>C p.V628A | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs771711060, COSV52574353; called by muse, mutect2, varscan2
- CDH26 | c.2359G>A p.E787K (on ENST00000348616 / NM_177980.4; = p.E120K on NM_021810.6) | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV54850093; called by muse, varscan2
- CDKN2D | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 236/457 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs778521084; called by muse, mutect2, varscan2
- CEL | c.460G>A p.A154T (on ENST00000673714; = p.A151T on NM_001807.6) | Missense Mutation (SNP) | VAF 287/644 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs373668445, COSV60826960; called by muse, mutect2, varscan2
- CEL | c.1763C>T p.T588M (on ENST00000673714; = p.T585M on NM_001807.6) | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs764120983; called by muse, mutect2
- CEP250 | c.5133G>T p.E1711D | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV61170686; called by muse, mutect2
- CEP350 | c.8183del p.N2728Tfs*7 | Frame Shift Del (DEL) | VAF 157/440 reads (36%) | catalogued as rs780253350; called by mutect2, pindel, varscan2
- CEP72 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 253/507 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs184127657; called by muse, mutect2, varscan2
- CETN3 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51618048; called by muse, mutect2, varscan2
- CFH | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as CM131605; called by muse, mutect2, varscan2
- CHD8 | c.2302G>A p.D768N (on ENST00000646647 / NM_001170629.2; = p.D489N on NM_020920.4) | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67871365; called by muse, mutect2, varscan2
- CNNM3 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 408/827 reads (49%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.899); catalogued as rs976057973; called by muse, mutect2, varscan2
- CNTNAP1 | c.1277G>A p.S426N | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52853062; called by muse, mutect2, varscan2
- COBL | c.246C>A p.S82R | Missense Mutation (SNP) | VAF 114/227 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV54347912; called by muse, mutect2, varscan2
- COG2 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 134/285 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs1356153361; called by muse, mutect2, varscan2
- COG4 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 203/471 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371160353; called by muse, mutect2, varscan2
- COL25A1 | c.1835A>G p.K612R | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs1162710644, COSV67660733; called by muse, mutect2, varscan2
- COL6A5 | c.1829del p.N610Mfs*16 | Frame Shift Del (DEL) | VAF 114/293 reads (39%) | catalogued as rs1388750145; called by mutect2, pindel, varscan2
- COQ4 | c.691T>C p.C231R | Missense Mutation (SNP) | VAF 31/607 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as rs1367308923, COSV55957879; called by muse, mutect2
- CPE | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 268/528 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV68580178, COSV68580955; called by muse, varscan2
- CRAMP1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 245/514 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1013059877; called by muse, mutect2, varscan2
- CRB1 | c.4147C>T p.R1383C | Missense Mutation (SNP) | VAF 204/454 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs1446146858; called by muse, mutect2, varscan2
- CRYBG1 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 483/945 reads (51%) | catalogued as COSV64812461; called by muse, mutect2, varscan2
- CSK | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 276/575 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54973503; called by muse, mutect2, varscan2
- CSMD2 | c.4865A>G p.Q1622R | Missense Mutation (SNP) | VAF 119/221 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.705); catalogued as rs1302174817; called by muse, mutect2, varscan2
- CSMD3 | c.10258G>A p.A3420T (on ENST00000297405 / NM_001363185.1; = p.A3251T on NM_052900.3) | Missense Mutation (SNP) | VAF 107/548 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1162260163, COSV99033678; called by muse, mutect2, varscan2
- CSN3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs1348977384; called by muse, mutect2
- CTSS | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 87/193 reads (45%) | catalogued as rs374721270; called by muse, mutect2, varscan2
- CTSW | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 269/570 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs755315802; called by muse, mutect2, varscan2
- CTTNBP2NL | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 202/490 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1481017205; called by muse, mutect2
- CYP2S1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 294/586 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs758328525; called by muse, varscan2
- DAGLA | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 145/301 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as rs775061931; called by muse, mutect2, varscan2
- DBX1 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 337/646 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs766999510; called by muse, mutect2, varscan2
- DDX11 | c.2532G>A p.R844= (on ENST00000545668 / NM_152438.2; = p.G796D on NM_004399.3) | Splice Region (SNP) | VAF 105/211 reads (50%) | catalogued as COSV99300149; called by muse, mutect2, varscan2
- DENND4B | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 112/875 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as rs750388751; called by muse, mutect2, varscan2
- DGKE | c.1582G>T p.G528W | Missense Mutation (SNP) | VAF 199/444 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV52350882; called by muse, mutect2, varscan2
- DGKK | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 440/443 reads (99%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.055); catalogued as rs781952576, COSV101052928; called by muse, varscan2
- DHH | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.157); catalogued as rs779174537; called by muse, varscan2
- DHODH | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1008004964; called by muse, mutect2, varscan2
- DHRS7 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 160/364 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1048906207; called by muse, mutect2, varscan2
- DHX34 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 242/461 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as rs754861045; called by muse, varscan2
- DHX36 | c.2739del p.F913Lfs*18 | Frame Shift Del (DEL) | VAF 156/414 reads (38%) | catalogued as rs1291917756; called by mutect2, pindel, varscan2
- DIAPH1 | c.2108dup p.P704Tfs*71 | Frame Shift Ins (INS) | VAF 41/150 reads (27%) | catalogued as rs771360300; called by mutect2, varscan2
- DIDO1 | c.5869C>T p.P1957S | Missense Mutation (SNP) | VAF 19/619 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs867504145, COSV56631869; called by muse, mutect2
- DLEU7 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 371/732 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1047915531; called by muse, mutect2, varscan2
- DLX5 | c.743del p.P248Qfs*61 | Frame Shift Del (DEL) | VAF 278/642 reads (43%) | catalogued as COSV99033613; called by mutect2, pindel, varscan2
- DMWD | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 224/454 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as rs759234003, COSV54287990; called by muse, mutect2, varscan2
- DNAH10 | c.8216C>T p.A2739V (on ENST00000409039; = p.A2678V on NM_207437.3) | Missense Mutation (SNP) | VAF 198/405 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1412228772; called by muse, mutect2, varscan2
- DNAH14 | c.971C>T p.S324L (on ENST00000445597; = p.S197L on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs779684244; called by muse, mutect2, varscan2
- DNAH2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 196/395 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as rs768754911, COSV50015282; called by muse, mutect2, varscan2
- DNAI4 | c.89dup p.W32Vfs*37 | Frame Shift Ins (INS) | VAF 216/460 reads (47%) | catalogued as rs774662919; called by mutect2, varscan2
- DNMT1 | c.2254A>G p.I752V | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1272046307; called by muse, mutect2, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 92/212 reads (43%) | catalogued as rs1559599687; called by mutect2, varscan2
- DOCK3 | c.5555dup p.A1853Sfs*46 | Frame Shift Ins (INS) | VAF 74/253 reads (29%) | catalogued as rs782552436; called by mutect2, varscan2
- DRAP1 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 129/305 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs759048752; called by muse, mutect2, varscan2
- DSCAM | c.4645C>T p.R1549W | Missense Mutation (SNP) | VAF 214/422 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs779003144, COSV101260082; called by muse, varscan2
- DSP | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 207/443 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs766022243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUOX2 | c.1831+1G>A p.X611_splice | Splice Site (SNP) | VAF 153/313 reads (49%) | catalogued as rs776473112; called by muse, mutect2, varscan2
- DUSP6 | c.875A>G p.H292R | Missense Mutation (SNP) | VAF 180/401 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs779946617, COSV99684228; called by muse, mutect2, varscan2
- DYNC1I2 | c.1258-1G>T p.X420_splice | Splice Site (SNP) | VAF 109/220 reads (50%) | catalogued as COSV99784315; called by muse, mutect2, varscan2
- DYSF | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 182/380 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV50299553; called by muse, mutect2, varscan2
- EDRF1 | c.3707C>T p.A1236V (on ENST00000356792 / NM_001202438.2; = p.A1202V on NM_015608.2) | Missense Mutation (SNP) | VAF 135/308 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61762551; called by muse, mutect2, varscan2
- EEF1A1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV100303454; called by muse, mutect2, varscan2
- EFHD1 | c.376del p.Q126Rfs*6 | Frame Shift Del (DEL) | VAF 249/591 reads (42%) | catalogued as rs760712775, COSV51135066; called by mutect2, pindel, varscan2
- EHBP1 | c.3299G>A p.R1100H | Missense Mutation (SNP) | VAF 136/267 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401104128; called by muse, varscan2
- EIF2AK4 | c.4426C>T p.R1476C | Missense Mutation (SNP) | VAF 154/350 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1161134551, COSV55467484; called by muse, mutect2, varscan2
- EIF4B | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 154/331 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs751632460; called by muse, mutect2, varscan2
- ELFN1 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 63/1060 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs781272692; called by muse, mutect2
- ELK3 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 64/741 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs1241142866, COSV57385977; called by muse, mutect2
- ELN | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 115/455 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs782775946; called by muse, mutect2, varscan2
- EMC1 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 153/373 reads (41%) | catalogued as rs548595466, COSV64345898; called by muse, mutect2, varscan2
- ENPEP | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs377134824; called by muse, mutect2, varscan2
- ENPEP | c.2723T>C p.M908T | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1233751656; called by muse, mutect2, varscan2
- EPC1 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 152/346 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143299306; called by muse, varscan2
- EPDR1 | c.576del p.F192Lfs*27 | Frame Shift Del (DEL) | VAF 53/448 reads (12%) | catalogued as COSV99554285; called by mutect2, pindel, varscan2
- EPHA5 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 16/593 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56676629; called by muse, mutect2
- EPHA8 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 37/649 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1390798586, COSV51262442; called by muse, mutect2
- EPN3 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 142/720 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1362425771, COSV52139814; called by muse, mutect2, varscan2
- EPS8L1 | c.1112G>A p.R371Q (on ENST00000201647 / NM_133180.3; = p.R244Q on NM_017729.3) | Missense Mutation (SNP) | VAF 397/855 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs749529084, COSV52384304; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 332/803 reads (41%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 81/205 reads (40%) | catalogued as rs753821453; called by mutect2, varscan2
- EVX1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 96/1112 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.124); catalogued as rs377423519; called by muse, mutect2
- EZHIP | c.904del p.R302Efs*145 | Frame Shift Del (DEL) | VAF 428/616 reads (69%) | catalogued as rs1557318834; called by mutect2, pindel, varscan2
- FAAH2 | c.743-1G>T p.X248_splice | Splice Site (SNP) | VAF 112/112 reads (100%) | catalogued as COSV100887175; called by muse, mutect2, varscan2
- FAM110A | c.199del p.V67Cfs*125 | Frame Shift Del (DEL) | VAF 383/973 reads (39%) | catalogued as COSV55726927; called by mutect2, pindel, varscan2
- FAM118A | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 162/373 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759418785, COSV53415984; called by muse, varscan2
- FAM120A | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 228/488 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs760644827, COSV99465422; called by muse, mutect2, varscan2
- FAM135A | c.4493C>T p.S1498L (on ENST00000370479 / NM_001351599.1; = p.S1285L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755261996, COSV52047993; called by muse, mutect2, varscan2
- FAM43A | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 314/668 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV61672702; called by muse, mutect2, varscan2
- FAM71B | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 269/556 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184587958; called by muse, mutect2, varscan2
- FAM81A | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779311597, COSV99893459; called by muse, varscan2
- FAN1 | c.34del p.R12Gfs*45 | Frame Shift Del (DEL) | VAF 72/188 reads (38%) | catalogued as rs752820596; called by mutect2, pindel, varscan2
- FAT3 | c.10615G>A p.V3539M | Missense Mutation (SNP) | VAF 171/379 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs531488417, COSV53070681, COSV53169706; called by muse, mutect2, varscan2
- FAT4 | c.10063G>T p.G3355* | Nonsense Mutation (SNP) | VAF 173/352 reads (49%) | catalogued as COSV58684876; called by muse, mutect2, varscan2
- FATE1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 328/328 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as rs777933414, COSV64848817; called by muse, mutect2, varscan2
- FBLN2 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 201/424 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as rs111606594, COSV99851716; called by muse, mutect2, varscan2
- FBN1 | c.7792C>A p.Q2598K | Missense Mutation (SNP) | VAF 183/384 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as CD075405; called by muse, mutect2, varscan2
- FBN2 | c.1697G>T p.R566M | Missense Mutation (SNP) | VAF 122/273 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.453); catalogued as COSV99326180; called by muse, mutect2, varscan2
- FBXL6 | c.1357A>G p.S453G | Missense Mutation (SNP) | VAF 282/1108 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100096203; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FER1L6 | c.4177C>T p.R1393W | Missense Mutation (SNP) | VAF 60/547 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376465322; called by muse, mutect2, varscan2
- FKBP6 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as rs1461093663; called by muse, mutect2, varscan2
- FLNC | c.5431C>T p.R1811W | Missense Mutation (SNP) | VAF 248/507 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs374794518; called by muse, mutect2, varscan2
- FLRT2 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 233/441 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs1381563121; called by muse, mutect2, varscan2
- FLT4 | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 291/549 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs745459631, COSV56105686; called by muse, mutect2, varscan2
- FOXG1 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 301/636 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100487141; called by muse, mutect2, varscan2
- FOXP4 | c.1391C>A p.A464D (on ENST00000307972 / NM_001012426.1; = p.A451D on NM_138457.3) | Missense Mutation (SNP) | VAF 210/477 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV57220047; called by muse, mutect2, varscan2
- FSCN2 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 304/624 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs781907499; called by muse, mutect2, varscan2
- FZD1 | c.623A>G p.Q208R | Missense Mutation (SNP) | VAF 67/628 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.579); catalogued as rs1227396990, COSV55310474; called by muse, mutect2, varscan2
- FZD5 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 253/532 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54944403; called by muse, mutect2, varscan2
- FZD7 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 308/733 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1337223448; called by muse, mutect2, varscan2
- G3BP2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 144/319 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs748613172; called by muse, varscan2
- GABRP | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 188/442 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1295546958; called by muse, mutect2, varscan2
- GALNT13 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV67213840; called by muse, mutect2, varscan2
- GALNT9 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 247/478 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs543179711; called by muse, mutect2, varscan2
- GATAD2A | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 185/456 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200707525; called by muse, mutect2, varscan2
- GBX1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 295/605 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775848180; called by muse, mutect2, varscan2
- GDF6 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 226/1005 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749537908, COSV54629041; called by muse, mutect2, varscan2
- GFER | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 209/422 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs760957301; called by muse, mutect2, varscan2
- GGT2 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1316847610; called by muse, mutect2, varscan2
- GHRHR | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 126/298 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs149678088; called by muse, mutect2, varscan2
- GIGYF1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 176/367 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as rs200730732; called by muse, mutect2, varscan2
- GJC2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 28/1032 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV104422113; called by muse, mutect2
- GLT1D1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV55879507; called by muse, mutect2, varscan2
- GLUD1 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 165/386 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1471790434, COSV53277528; called by muse, mutect2, varscan2
- GNPTAB | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 225/484 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68450029; called by muse, mutect2, varscan2
- GPC1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 316/598 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs543077300, COSV50864532; called by muse, mutect2, varscan2
- GRIN1 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 216/438 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV59300262; called by muse, mutect2, varscan2
- GRK3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 45/192 reads (23%) | catalogued as rs775857408, COSV100151897, COSV60792833; called by muse, mutect2, varscan2
- GRN | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 170/392 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50006566; called by muse, mutect2, varscan2
- GUCY1B1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1010660172, COSV100025425; called by muse, mutect2, varscan2
- GZF1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 277/533 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs891711571, COSV100582482; called by muse, mutect2, varscan2
- GZF1 | c.1604A>G p.Y535C | Missense Mutation (SNP) | VAF 126/290 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1458763070; called by muse, mutect2, varscan2
- H2BC18 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 214/520 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as rs782084416; called by muse, varscan2
- H3C2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 257/560 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as rs866029344; called by muse, mutect2, varscan2
- HBB | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 259/581 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs33990858, CM086834, CM930376, COSV100092745; ClinVar: likely benign / other; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 224/508 reads (44%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HCN1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 232/553 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1374925949; called by mutect2, varscan2
- HDAC5 | c.1722G>T p.E574D | Missense Mutation (SNP) | VAF 306/630 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56818943; called by muse, mutect2, varscan2
- HDGFL2 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 217/454 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs769090414, COSV56682191; called by muse, mutect2, varscan2
- HES6 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 365/740 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV56028662; called by muse, varscan2
- HLA-DOB | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as rs1242945335; called by muse, mutect2, varscan2
- HLA-DQB2 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 32/658 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (1); catalogued as rs1339217127, COSV68614935; called by muse, mutect2
- HMX1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 179/349 reads (51%) | catalogued as COSV72467066; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.62G>A p.R21H (on ENST00000354667 / NM_031243.3; = p.R9H on NM_002137.4) | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV100523038, COSV61158670; called by muse, mutect2, varscan2
- HNRNPK | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 129/275 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs753749781; called by muse, mutect2, varscan2
- HSF4 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 211/467 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1162233829; called by muse, mutect2, varscan2
- HTR6 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 358/770 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200329647, COSV57033044; called by muse, mutect2, varscan2
- HTR6 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 321/668 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs773507179; called by muse, mutect2, varscan2
- IFT172 | c.4160G>T p.R1387M | Missense Mutation (SNP) | VAF 150/315 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV53130684; called by muse, mutect2, varscan2
- IFT172 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 250/519 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868020223, COSV99563550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF2R | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 150/326 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as rs8191797; called by muse, mutect2, varscan2
- IGF2R | c.7093A>G p.N2365D | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV63628165; called by muse, mutect2
- IGHE | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 20/526 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.186); catalogued as rs782611499; called by muse, mutect2
- IGHG4 | c.698del p.P233Hfs*6 | Frame Shift Del (DEL) | VAF 255/2402 reads (11%) | catalogued as rs1187597015; called by mutect2, pindel, varscan2
- IGSF10 | c.6847G>A p.A2283T | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318791976; called by muse, mutect2, varscan2
- IGSF9B | c.2655G>A p.M885I | Missense Mutation (SNP) | VAF 306/659 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs751924626; called by muse, varscan2
- IKZF1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 347/707 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV58780665; called by muse, varscan2
- IL26 | c.188del p.N63Ifs*5 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs778805733; called by mutect2, pindel
- IL4 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 215/422 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757467461; called by muse, mutect2, varscan2
- INSYN2A | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 216/460 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as rs755851502, COSV54762443; called by muse, varscan2
- INTS11 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 228/485 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1200250549; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 48/88 reads (55%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQCG | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 194/449 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs1185081980; called by muse, mutect2, varscan2
- IQCJ | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 17/454 reads (4%) | catalogued as rs1195359448; called by muse, mutect2
- IRAK1 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs782768715, COSV64110331; called by muse, mutect2
- IRF1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 211/429 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232351516, COSV55376923; called by muse, mutect2, varscan2
- IRF4 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 301/587 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs752393433, COSV66704538; called by muse, mutect2, varscan2
- IRGC | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 240/625 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.771); catalogued as rs1263848948, COSV54985117; called by muse, mutect2, varscan2
- IRS1 | c.2213T>C p.V738A | Missense Mutation (SNP) | VAF 236/489 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs771926934, COSV59333327; called by muse, varscan2
- IRS2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 56/1036 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65480068; called by muse, mutect2
- ISL1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 289/639 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57934462; called by muse, mutect2, varscan2
- ISLR2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 313/656 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1395632632, COSV100679355; called by muse, mutect2, varscan2
- ITGA2B | c.1558A>G p.M520V | Missense Mutation (SNP) | VAF 190/396 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs762055902; called by muse, mutect2, varscan2
- ITGA4 | c.1774A>C p.S592R | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.567); catalogued as rs1334640877; called by muse, mutect2
- ITK | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 222/472 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV70065002; called by muse, mutect2, varscan2
- ITPKB | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 275/576 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs772745613; called by muse, mutect2, varscan2
- JAK3 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 268/546 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs1348255401; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 222/494 reads (45%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- JARID2 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 245/522 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1157174829; called by muse, mutect2, varscan2
- KBTBD13 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 310/617 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs757520982; called by muse, mutect2, varscan2
- KCNG2 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 353/722 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV60267604; called by muse, mutect2, varscan2
- KCNK15 | c.778del p.T260Pfs*105 | Frame Shift Del (DEL) | VAF 207/462 reads (45%) | catalogued as rs1555858007, COSV65719629, COSV65720794; called by mutect2, varscan2
- KCNQ1 | c.1685G>T p.R562M | Missense Mutation (SNP) | VAF 240/500 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199472802, CM030229; ClinVar: not provided; called by muse, mutect2, varscan2
- KCNQ4 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 157/337 reads (47%) | catalogued as rs376909924; called by muse, mutect2, varscan2
- KCNRG | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 185/391 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs1400568549; called by muse, mutect2, varscan2
- KHNYN | c.1544T>C p.M515T | Missense Mutation (SNP) | VAF 159/335 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs760304162, COSV52162207; called by muse, mutect2, varscan2
- KIAA1522 | c.2153C>A p.P718H (on ENST00000373480 / NM_001198972.2; = p.P777H on NM_020888.3) | Missense Mutation (SNP) | VAF 167/399 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99615028; called by mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 182/403 reads (45%) | catalogued as rs752375544, COSV54318481; called by mutect2, varscan2
- KIF26B | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 208/466 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.364); catalogued as rs1431227540, COSV100833370; called by muse, mutect2, varscan2
- KIF5B | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 19/437 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56652702; called by muse, mutect2
- KIR2DL3 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 140/473 reads (30%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.461); catalogued as rs1304295899; called by muse, mutect2
- KLF16 | c.290del p.G97Afs*48 | Frame Shift Del (DEL) | VAF 346/836 reads (41%) | catalogued as rs1413895006; called by mutect2, pindel, varscan2
- KLF4 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 316/682 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs763076292; called by muse, mutect2, varscan2
- KLHL33 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 266/524 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1156942528; called by muse, varscan2
- KLHL36 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 290/602 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs368978011; called by muse, mutect2, varscan2
- KLHL41 | c.1296dup p.L433Tfs*9 | Frame Shift Ins (INS) | VAF 21/77 reads (27%) | catalogued as rs1288106608; called by mutect2, varscan2
- KMT2D | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 218/474 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs776778856, CM165013; called by muse, mutect2, varscan2
- KNDC1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 321/645 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867023153; called by muse, varscan2
- KRT16 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 444/912 reads (49%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.579); catalogued as rs751458816; called by muse, mutect2, varscan2
- KRT24 | c.110del p.G37Afs*16 | Frame Shift Del (DEL) | VAF 247/622 reads (40%) | catalogued as rs772344547, COSV99232217; called by mutect2, pindel, varscan2
- KRT6B | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 159/329 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs367794230; called by muse, mutect2, varscan2
- KRT85 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 319/712 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV57736818; called by muse, mutect2, varscan2
- KRTAP4-7 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 415/814 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as rs760145100; called by muse, mutect2, varscan2
- LAMB4 | c.26dup p.L9Ffs*14 | Frame Shift Ins (INS) | VAF 62/158 reads (39%) | catalogued as rs747409331; called by mutect2, varscan2
- LAMC3 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 28/1078 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1399381610; called by muse, mutect2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 195/271 reads (72%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LATS1 | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53591003, COSV53591320; called by muse, mutect2
- LCP1 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 167/362 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898832393; called by muse, mutect2, varscan2
- LGALS3BP | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 204/485 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1286831176; called by muse, mutect2, varscan2
- LHFPL2 | c.8A>G p.H3R | Missense Mutation (SNP) | VAF 140/307 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs116579975; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 172/388 reads (44%) | catalogued as rs748712732; called by mutect2, varscan2
- LPIN1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 195/447 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1172290138; called by muse, mutect2, varscan2
- LRBA | c.2409G>T p.Q803H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV63966511; called by muse, mutect2, varscan2
- LRFN2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 234/481 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761701287, COSV100599326, COSV57826756; called by muse, mutect2, varscan2
- LRIG2 | c.225dup p.D76Rfs*10 | Frame Shift Ins (INS) | VAF 245/576 reads (43%) | catalogued as rs768751013; called by mutect2, pindel, varscan2
- LRRN3 | c.1243A>G p.M415V | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs1192824677; called by muse, mutect2
- LY75 | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 171/359 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1050268604, COSV99716363; called by muse, mutect2, varscan2
- LY9 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs200948203, COSV99627567; called by muse, mutect2
- LYVE1 | c.595T>A p.L199M | Missense Mutation (SNP) | VAF 121/256 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs200474910; called by muse, mutect2, varscan2
- MACROD1 | c.241del p.L81Wfs*9 | Frame Shift Del (DEL) | VAF 96/875 reads (11%) | catalogued as rs1423172365; called by mutect2, pindel, varscan2
- MAN2B1 | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 281/534 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as rs755553683, COSV99667155; called by muse, mutect2, varscan2
- MAN2B1 | c.2627G>C p.G876A | Missense Mutation (SNP) | VAF 373/678 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs1413967043, COSV55472948; called by muse, mutect2, varscan2
- MAP1S | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 351/757 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs200408004; called by muse, mutect2, varscan2
- MAP3K1 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs777628678, COSV68128001; called by muse, mutect2, varscan2
- MAP3K14 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 193/422 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs759696785, COSV60922773; called by muse, mutect2, varscan2
- MAP3K15 | c.3887C>T p.A1296V | Missense Mutation (SNP) | VAF 157/158 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs756039907, COSV58835321; called by muse, mutect2, varscan2
- MAP4K3 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252160971, COSV55713408, COSV55716811; called by muse, mutect2, varscan2
- MAPK8IP1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 54/828 reads (7%) | catalogued as rs368102116; called by muse, mutect2
- MBD1 | c.1054C>T p.R352C (on ENST00000269468 / NM_001323950.1; = p.R329C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 298/657 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1424033110, COSV53999035; called by muse, varscan2
- MCF2L | c.734C>T p.A245V (on ENST00000375608; = p.A213V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 280/594 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65052545; called by muse, mutect2, varscan2
- MEGF6 | c.3704G>A p.R1235H | Missense Mutation (SNP) | VAF 269/602 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs768091930; called by muse, mutect2, varscan2
- MEGF8 | c.6799C>T p.R2267C (on ENST00000251268 / NM_001271938.2; = p.R2200C on NM_001410.3) | Missense Mutation (SNP) | VAF 208/469 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs1568576351; called by muse, mutect2, varscan2
- MEX3D | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 366/689 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.743); catalogued as COSV66311779; called by muse, mutect2, varscan2
- MFAP2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 162/406 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750857678; called by muse, mutect2
- MFSD12 | c.1291T>C p.S431P | Missense Mutation (SNP) | VAF 223/500 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs1424384960; called by muse, mutect2, varscan2
- MINDY2 | c.1847del p.N616Ifs*41 | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | catalogued as rs1282883369; called by mutect2, pindel, varscan2
- MINK1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 144/448 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs545655356, COSV61790961; called by muse, mutect2, varscan2
- MLH3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs751375245, COSV53136067; called by muse, mutect2, varscan2
- MMP2 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 152/396 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.42); catalogued as rs1416177273; called by muse, mutect2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 112/266 reads (42%) | catalogued as rs782038929; called by mutect2, varscan2
- MOV10L1 | c.1231del p.T411Pfs*27 | Frame Shift Del (DEL) | VAF 175/473 reads (37%) | catalogued as rs942723014; called by mutect2, pindel, varscan2
- MPO | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 262/588 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs367635034; called by muse, mutect2, varscan2
- MROH1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 54/1014 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759517651; called by muse, mutect2
- MRPL19 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 238/556 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.241); catalogued as rs769631282; called by mutect2, varscan2
- MRPL37 | c.205T>C p.W69R | Missense Mutation (SNP) | VAF 326/685 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs971192110; called by muse, mutect2, varscan2
- MRPS30 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV50181902; called by muse, mutect2, varscan2
- MRPS5 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 126/251 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534303990; called by muse, mutect2, varscan2
- MS4A5 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs374217276; called by muse, mutect2, varscan2
- MTA1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 256/557 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs587731412, COSV58755672, COSV58756563; called by muse, mutect2, varscan2
- MTA3 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 146/313 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs775951008; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 75/189 reads (40%) | catalogued as rs759847587; called by mutect2, varscan2
- MTSS2 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 274/604 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761912285, COSV55381224; called by muse, varscan2
- MTUS2 | c.1877G>T p.R626M | Missense Mutation (SNP) | VAF 269/548 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1272055311, COSV70920375; called by muse, mutect2, varscan2
- MUC1 | c.3616G>A p.A1206T (on ENST00000611571 / NM_001371720.1; = p.A217T on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 298/600 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV100104506; called by muse, mutect2, varscan2
- MUC16 | c.30869C>T p.A10290V | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.198); catalogued as rs1157386502; called by muse, mutect2, varscan2
- MUC16 | c.14995del p.Q4999Rfs*8 | Frame Shift Del (DEL) | VAF 175/472 reads (37%) | catalogued as rs778508627, COSV99064211; called by mutect2, pindel, varscan2
- MXRA5 | c.8060G>A p.R2687H | Missense Mutation (SNP) | VAF 366/370 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755067368, COSV54231763; called by muse, varscan2
- MYBPC1 | c.1022C>T p.P341L (on ENST00000550270 / NM_206820.2; = p.P366L on NM_002465.4) | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100638127; called by muse, mutect2, varscan2
- MYBPC2 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.405); catalogued as rs552817311; called by muse, mutect2, varscan2
- MYH10 | c.3071del p.N1024Tfs*11 | Frame Shift Del (DEL) | VAF 133/334 reads (40%) | catalogued as COSV99345962; called by mutect2, pindel, varscan2
- MYH14 | c.2784del p.R929Gfs*44 | Frame Shift Del (DEL) | VAF 267/696 reads (38%) | catalogued as COSV51828005; called by mutect2, pindel, varscan2
- MYH6 | c.2558C>T p.T853I | Missense Mutation (SNP) | VAF 314/624 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV62453824; called by muse, mutect2, varscan2
- MYH7 | c.4058C>T p.A1353V | Missense Mutation (SNP) | VAF 328/694 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs376040196, COSV62521486; called by muse, mutect2, varscan2
- MYO16 | c.4940C>T p.A1647V | Missense Mutation (SNP) | VAF 406/838 reads (48%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as rs138518678; called by muse, mutect2, varscan2
- MYO7B | c.3679G>A p.A1227T | Missense Mutation (SNP) | VAF 177/510 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1558843466, COSV67351720; called by muse, mutect2, varscan2
- MYORG | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 252/537 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs770993685; called by muse, varscan2
- NACC1 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 193/392 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as rs958808508; called by muse, mutect2, varscan2
- NAF1 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1196513032; called by muse, mutect2, varscan2
- NAGPA | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 233/483 reads (48%) | catalogued as rs1407516561; called by muse, mutect2, varscan2
- NCKIPSD | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 443/905 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs1351724358; called by muse, mutect2, varscan2
- NCOA6 | c.1997del p.P666Rfs*12 | Frame Shift Del (DEL) | VAF 212/534 reads (40%) | catalogued as rs763811545; called by mutect2, pindel, varscan2
- NCOR1 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 203/438 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV51995987; called by muse, mutect2, varscan2
- NDUFB8 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs775076125, COSV54511334; called by muse, mutect2, varscan2
- NDUFS1 | c.2119A>G p.M707V | Missense Mutation (SNP) | VAF 47/394 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs775839833, CM012413; called by muse, mutect2, varscan2
- NDUFS7 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 364/761 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs925435610, COSV99282809; called by muse, mutect2, varscan2
- NEB | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs761337214; called by muse, mutect2, varscan2
- NECTIN1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 246/537 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761246972, COSV50608938; called by muse, varscan2
- NEIL2 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 231/498 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52707150; called by muse, mutect2, varscan2
- NGEF | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 257/589 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs767845515; called by muse, mutect2, varscan2
- NIBAN1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 243/452 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62287770; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 91/657 reads (14%) | catalogued as COSV53499514; called by mutect2, varscan2
- NKPD1 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 46/661 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as rs931261091, COSV58728899; called by muse, mutect2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 334/935 reads (36%) | catalogued as rs745904099; called by pindel, varscan2
- NLRP2B | c.106G>T p.G36* | Nonsense Mutation (SNP) | VAF 160/160 reads (100%) | catalogued as COSV70505904; called by muse, mutect2, varscan2
- NOTCH4 | c.4912del p.L1638Cfs*68 | Frame Shift Del (DEL) | VAF 509/1343 reads (38%) | catalogued as rs767972771; called by mutect2, pindel, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 238/594 reads (40%) | catalogued as rs765756993; called by pindel, varscan2
- NPAS3 | c.2671G>A p.A891T (on ENST00000356141 / NM_001164749.2; = p.A859T on NM_022123.3) | Missense Mutation (SNP) | VAF 285/569 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs746451563, COSV60856245; called by muse, mutect2, varscan2
- NPHP1 | c.2098G>A p.A700T (on ENST00000393272 / NM_207181.4; = p.A701T on NM_000272.5) | Missense Mutation (SNP) | VAF 237/521 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as rs201077898; called by muse, mutect2, varscan2
- NPIPB5 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 194/1022 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs1366785632; called by muse, varscan2
- NR1H3 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 271/574 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs766271635; called by muse, mutect2, varscan2
- NRP2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 223/468 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs555467484, COSV99783831, COSV99785676; called by muse, mutect2
- NRXN3 | c.1561C>T p.L521F (on ENST00000335750 / NM_001330195.2; = p.L148F on NM_004796.6) | Missense Mutation (SNP) | VAF 203/411 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1326966067, COSV59814485; called by muse, mutect2, varscan2
- NTN5 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 220/997 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.019); catalogued as rs1406025933; called by muse, mutect2, varscan2
- NUDT8 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 209/404 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs201276154; called by muse, mutect2, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 136/274 reads (50%) | catalogued as rs772197760; called by mutect2, varscan2
- NUP188 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 142/295 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1044136595; called by muse, mutect2, varscan2
- NUP54 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 165/332 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs754816608; called by muse, mutect2, varscan2
- NUP62 | c.845_850del p.T282_S283del | In Frame Del (DEL) | VAF 134/432 reads (31%) | catalogued as rs1038713350; called by pindel, varscan2
- NUS1 | c.49T>C p.C17R | Missense Mutation (SNP) | VAF 254/525 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.07); catalogued as rs1245004786; called by muse, mutect2, varscan2
- NXPH2 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55642125; called by muse, mutect2, varscan2
- NYAP1 | c.1603del p.H535Tfs*8 | Frame Shift Del (DEL) | VAF 290/598 reads (48%) | catalogued as COSV55718985; called by mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 101/257 reads (39%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OCA2 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 208/476 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV100668859; called by muse, mutect2
- ODF3 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 76/606 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1477888796; called by muse, mutect2, varscan2
- OGDHL | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759331380; called by muse, mutect2
- OLFM4 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 68/179 reads (38%) | catalogued as rs767153443; called by muse, mutect2, varscan2
- OR2I1P | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 289/623 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.862); catalogued as rs1393876644; called by muse, mutect2, varscan2
- OR4C11 | c.779dup p.T261Dfs*53 | Frame Shift Ins (INS) | VAF 176/251 reads (70%) | catalogued as rs764963140; called by mutect2, pindel, varscan2
- OR4K13 | c.901del p.R301Dfs*71 | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | catalogued as rs749899868, COSV100237879; called by mutect2, pindel, varscan2
- OR4K15 | c.346A>G p.I116V (on ENST00000305051; = p.I92V on NM_001005486.1) | Missense Mutation (SNP) | VAF 213/436 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100521188; called by muse, mutect2, varscan2
- OR51B5 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100332594; called by muse, mutect2
- OR51B5 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 241/487 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56175716, COSV56177519; called by muse, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 127/231 reads (55%) | catalogued as rs746200712; called by mutect2, varscan2
- OSGEPL1 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749109122, COSV99918351; called by muse, mutect2, varscan2
- OTOG | c.7846C>T p.R2616C | Missense Mutation (SNP) | VAF 228/453 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs876657944, COSV61131277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTOGL | c.838G>A p.A280T (on ENST00000547103; = p.A271T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.399); catalogued as rs200599746; called by muse, varscan2
- P2RY8 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 1092/1093 reads (100%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as rs751008443, COSV67176987; called by muse, mutect2, varscan2
- P3H1 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 49/660 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104376813, COSV52535840; called by muse, mutect2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 143/279 reads (51%) | catalogued as rs763394045; called by mutect2, varscan2
- PAGE2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 128/129 reads (99%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100892289; called by muse, mutect2, varscan2
- PAK4 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 305/642 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs146498509; called by muse, mutect2, varscan2
- PAM | c.1298del p.K433Rfs*32 | Frame Shift Del (DEL) | VAF 188/459 reads (41%) | catalogued as rs1235994663; called by mutect2, pindel, varscan2
- PAN2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 106/242 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777411298, COSV57756099; called by muse, mutect2, varscan2
- PARS2 | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 186/384 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64883557; called by muse, mutect2, varscan2
- PAX8 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 265/557 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV54512647; called by muse, mutect2, varscan2
- PAXIP1 | c.2274del p.A759Pfs*25 | Frame Shift Del (DEL) | VAF 37/423 reads (9%) | catalogued as COSV68187329; called by mutect2, pindel
- PCDHB8 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 400/1070 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.03); catalogued as rs1554281457, COSV50755916; called by muse, mutect2
- PCDHGB2 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 121/475 reads (25%) | catalogued as COSV99536038; called by muse, mutect2, varscan2
- PCDHGB5 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 299/628 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs1460072742; called by muse, mutect2, varscan2
- PCDHGB5 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 269/594 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV54009202; called by muse, mutect2, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 224/601 reads (37%) | catalogued as rs772305388; called by mutect2, pindel, varscan2
- PCF11 | c.1942G>T p.A648S | Missense Mutation (SNP) | VAF 117/349 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as COSV53531892; called by muse, mutect2, varscan2
- PCSK1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 43/625 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV60733480; called by muse, mutect2
- PDCD6 | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 160/355 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs138896105; called by muse, mutect2, varscan2
- PDIA2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 277/591 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.163); catalogued as rs202228688, COSV51988094; called by muse, mutect2, varscan2
- PDIA4 | c.1331A>G p.K444R (on ENST00000286091 / NM_001371244.1; = p.K443R on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs766111632; called by muse, mutect2, varscan2
- PDZD2 | c.4248del p.S1419Vfs*6 | Frame Shift Del (DEL) | VAF 278/674 reads (41%) | catalogued as rs113511990, COSV56865110; called by mutect2, pindel, varscan2
- PER1 | c.1388+1G>A p.X463_splice | Splice Site (SNP) | VAF 209/431 reads (48%) | catalogued as COSV57922525; called by muse, mutect2, varscan2
- PER1 | c.833G>T p.W278L | Missense Mutation (SNP) | VAF 183/389 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100424586; called by muse, mutect2, varscan2
- PERCC1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 28/698 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs974426317; called by muse, mutect2
- PFKP | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 178/380 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1350672515, COSV66895903; called by muse, varscan2
- PGBD5 | c.474del p.H158Qfs*33 (on ENST00000525115; = p.H227Qfs*33 on NM_001258311.2) | Frame Shift Del (DEL) | VAF 195/495 reads (39%) | catalogued as COSV58410306, COSV58410659; called by mutect2, pindel, varscan2
- PHLPP1 | c.2977G>A p.A993T | Missense Mutation (SNP) | VAF 28/357 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1334065538, COSV53022703; called by muse, mutect2
- PHLPP1 | c.4193C>T p.A1398V | Missense Mutation (SNP) | VAF 295/573 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1486896209; called by muse, mutect2, varscan2
- PHRF1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 327/671 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs751137395; called by muse, mutect2, varscan2
- PIF1 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 410/754 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs897160606; called by muse, mutect2, varscan2
- PIK3C2A | c.3019G>A p.A1007T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.166); catalogued as COSV56401642; called by muse, mutect2, varscan2
- PIK3CG | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 231/459 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs200175951, COSV63245400; called by muse, mutect2, varscan2
- PIK3CG | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1184325643, COSV63247994; called by muse, mutect2, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 56/377 reads (15%) | catalogued as rs755454854; called by mutect2, varscan2
- PIP4K2C | c.393dup p.S132Qfs*4 | Frame Shift Ins (INS) | VAF 160/346 reads (46%) | catalogued as rs750999963; called by mutect2, varscan2
- PIP5K1C | c.1794G>T p.E598D | Missense Mutation (SNP) | VAF 237/482 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV58952071; called by muse, mutect2, varscan2
- PITPNM1 | c.3515C>T p.A1172V | Missense Mutation (SNP) | VAF 289/596 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.314); catalogued as rs139473273; called by muse, mutect2, varscan2
- PKD1L1 | c.8452dup p.T2818Nfs*20 | Frame Shift Ins (INS) | VAF 189/475 reads (40%) | catalogued as rs761514270; called by mutect2, pindel, varscan2
- PKM | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs978437292, COSV100065102; called by muse, mutect2, varscan2
- PKN2 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs201995133; called by muse, mutect2, varscan2
- PLAT | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 52/698 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1224060830; called by muse, mutect2
- PLEC | c.2285C>T p.A762V (on ENST00000322810 / NM_201380.4; = p.A652V on NM_000445.5) | Missense Mutation (SNP) | VAF 228/882 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs369665294; called by muse, varscan2
- PLEKHG6 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 258/741 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs746601174; called by muse, mutect2, varscan2
- PLIN4 | c.3952C>T p.Q1318* (on ENST00000301286; = p.Q1333* on NM_001367868.2) | Nonsense Mutation (SNP) | VAF 46/824 reads (6%) | catalogued as rs1230564800; called by muse, mutect2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 152/330 reads (46%) | catalogued as rs746342377; called by mutect2, varscan2
- PLPPR4 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 237/477 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV64565429; called by muse, mutect2, varscan2
- PLXNA1 | c.2374G>A p.G792S | Missense Mutation (SNP) | VAF 204/427 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs140406218; called by muse, mutect2, varscan2
- PNKD | c.43dup p.A15Gfs*17 | Frame Shift Ins (INS) | VAF 254/653 reads (39%) | catalogued as rs777779692; called by mutect2, pindel, varscan2
- PNMA1 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 220/443 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV99679073; called by muse, varscan2
- PNPLA5 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 263/537 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53376309; called by muse, mutect2, varscan2
- PNPLA6 | c.1368del p.S457Pfs*59 (on ENST00000414982 / NM_001166111.2; = p.S409Pfs*59 on NM_006702.5) | Frame Shift Del (DEL) | VAF 203/551 reads (37%) | catalogued as COSV55373526; called by mutect2, pindel, varscan2
- POFUT2 | c.1143del p.F381Lfs*101 | Frame Shift Del (DEL) | VAF 90/174 reads (52%) | catalogued as COSV100499227; called by mutect2, varscan2
- POLG | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 168/376 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51521290; called by muse, mutect2, varscan2
- POLQ | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs931174372, COSV51748511; called by muse, mutect2, varscan2
- POLR2E | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 203/453 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778316755, COSV99297865; called by muse, mutect2, varscan2
- POTEJ | c.2317del p.L773* | Frame Shift Del (DEL) | VAF 249/691 reads (36%) | catalogued as rs1355269033; called by mutect2, pindel, varscan2
- PPM1J | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 181/397 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs1360121627; called by muse, mutect2, varscan2
- PPP1R13L | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 355/762 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); catalogued as COSV62909329; called by muse, mutect2, varscan2
- PRDM8 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 183/378 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1477581300; called by muse, mutect2, varscan2
- PRELID1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 231/486 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100293388; called by muse, mutect2, varscan2
- PREX2 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1275528365; called by muse, mutect2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 98/181 reads (54%) | catalogued as rs764112302; called by mutect2, varscan2
- PRICKLE3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 15/389 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs924173387, COSV66234551; called by muse, mutect2
- PRKCH | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1360578025, COSV60647083; called by muse, mutect2, varscan2
- PRPF31 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 321/691 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.069); catalogued as rs766301461; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR23B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.211); catalogued as rs754211034, COSV61493204; called by muse, mutect2, varscan2
- PRRC2B | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 118/238 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1377150365; called by muse, mutect2, varscan2
- PSD3 | c.3083G>A p.R1028H (on ENST00000440756; = p.R1027H on NM_015310.4) | Missense Mutation (SNP) | VAF 361/361 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs551637019, COSV99677195; called by muse, mutect2, varscan2
- PTCHD3 | c.1764del p.F588Lfs*18 | Frame Shift Del (DEL) | VAF 130/298 reads (44%) | catalogued as rs1448522271; called by mutect2, pindel, varscan2
- PTGFRN | c.889C>A p.L297M | Missense Mutation (SNP) | VAF 198/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67798084; called by muse, mutect2, varscan2
- PTOV1 | c.1248dup p.*417Vfs*24 (on ENST00000391842; = p.*417Vfs*77 on NM_017432.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 216/468 reads (46%) | catalogued as rs750392317; called by mutect2, varscan2
- PTPN13 | c.4249C>T p.R1417C (on ENST00000411767 / NM_080683.3; = p.R1398C on NM_006264.3) | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757638920; called by muse, mutect2, varscan2
- PTPRK | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 147/332 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs983513819, COSV100950417; called by muse, mutect2, varscan2
- PTPRS | c.1865del p.P622Lfs*16 | Frame Shift Del (DEL) | VAF 84/195 reads (43%) | catalogued as rs755108907; called by mutect2, pindel, varscan2
- QARS1 | c.1736T>C p.I579T | Missense Mutation (SNP) | VAF 210/428 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs748878219; called by muse, mutect2, varscan2
- R3HDM4 | c.263del p.G88Afs*36 | Frame Shift Del (DEL) | VAF 227/593 reads (38%) | catalogued as COSV100846435; called by mutect2, pindel, varscan2
- RAB4A | c.111del p.K37Nfs*10 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs781323910; called by mutect2, varscan2
- RABGAP1 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs765066888, COSV101017040; called by muse, mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 163/410 reads (40%) | catalogued as rs1251406873; called by mutect2, pindel, varscan2
- RAPGEF3 | c.1243+1G>A p.X415_splice (on ENST00000389212; = p.X373_splice on NM_006105.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 151/331 reads (46%) | catalogued as rs1164309354; called by muse, mutect2, varscan2
- RAPGEF4 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 156/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1418578375, COSV51379706, COSV51406662; called by muse, mutect2, varscan2
- RARS2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs746493119, CM1312353; called by muse, mutect2, varscan2
- RASL10A | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 420/883 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748408760; called by muse, mutect2, varscan2
- RBM7 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as COSV57784837; called by muse, mutect2, varscan2
- RBMXL3 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 87/398 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.29); catalogued as rs982344962; called by muse, mutect2, varscan2
- RCC2 | c.1558del p.R520Efs*55 | Frame Shift Del (DEL) | VAF 167/422 reads (40%) | catalogued as COSV100965161; called by mutect2, pindel, varscan2
- RECQL4 | c.216G>A p.A72= | Splice Region (SNP) | VAF 217/982 reads (22%) | catalogued as rs753073753; called by muse, mutect2, varscan2
- RECQL5 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 237/518 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs373202958; called by muse, mutect2, varscan2
- RFNG | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as rs1229436243; called by muse, mutect2
- RIIAD1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 242/512 reads (47%) | SIFT deleterious, low confidence (0); catalogued as rs970401010; called by muse, mutect2, varscan2
- RIPOR2 | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 262/537 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756046392; called by muse, mutect2, varscan2
- RLF | c.4255del p.Y1419Ifs*6 | Frame Shift Del (DEL) | VAF 150/361 reads (42%) | catalogued as COSV65652466; called by mutect2, pindel, varscan2
- RNF5 | c.526del p.W176Gfs*22 | Frame Shift Del (DEL) | VAF 264/656 reads (40%) | catalogued as rs758165894; called by mutect2, pindel, varscan2
- RPL10 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV50010532; called by muse, mutect2
- RSPH10B2 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1241152497; called by mutect2, varscan2
- RTTN | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV55343328; called by muse, mutect2, varscan2
- RUNX2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs11498200; called by muse, mutect2, varscan2
- RYR2 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs766802574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 276/608 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs750975954, COSV51763325; called by muse, mutect2, varscan2
- SASS6 | c.567dup p.Q190Tfs*5 | Frame Shift Ins (INS) | VAF 87/175 reads (50%) | catalogued as rs778258887; called by mutect2, varscan2
- SCARF1 | c.1867del p.A623Rfs*66 | Frame Shift Del (DEL) | VAF 365/769 reads (47%) | catalogued as rs34681910; called by mutect2, varscan2
- SCLY | c.185T>C p.M62T (on ENST00000651534; = p.M54T on NM_016510.7) | Missense Mutation (SNP) | VAF 164/316 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs934122999; called by muse, mutect2, varscan2
- SCN9A | c.2764C>T p.R922C (on ENST00000303354; = p.R911C on NM_002977.3) | Missense Mutation (SNP) | VAF 183/414 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774848595, COSV100312528, COSV57608654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1D | c.1071G>T p.E357D (on ENST00000338555; = p.E521D on NM_001130413.4) | Missense Mutation (SNP) | VAF 210/431 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs1486756473; called by muse, mutect2, varscan2
- SDK1 | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 205/415 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1234230941; called by muse, mutect2, varscan2
- SDR42E2 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 184/431 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs1182460935; called by muse, varscan2
- SEC16B | c.2312G>A p.S771N | Missense Mutation (SNP) | VAF 254/542 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1468295147; called by muse, varscan2
- SEC61A1 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 63/603 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV54578494; called by muse, mutect2, varscan2
- SEPTIN1 | c.575G>A p.G192D (on ENST00000321367; = p.G145D on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/267 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs942093928; called by muse, mutect2, varscan2
- SERAC1 | c.486T>C p.H162= | Splice Region (SNP) | VAF 119/231 reads (52%) | catalogued as rs1341795860, COSV100894889; called by muse, mutect2, varscan2
- SERPINA11 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 34/575 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.788); catalogued as rs563316230, COSV58241320; called by muse, mutect2
- SERPINB9 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 170/380 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV66233550; called by muse, varscan2
- SERPINH1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 281/542 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs535510332, COSV63998178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF3B3 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 204/444 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV56787147; called by muse, mutect2, varscan2
- SF3B6 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 113/222 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs368219315; called by muse, mutect2, varscan2
- SGO1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs999124851, COSV55423844; called by muse, mutect2
- SGO2 | c.1943del p.F648Sfs*14 | Frame Shift Del (DEL) | VAF 48/97 reads (49%) | catalogued as rs771387868; called by mutect2, varscan2
- SGSM2 | c.1541G>T p.R514L (on ENST00000426855 / NM_001098509.2; = p.R559L on NM_014853.3) | Missense Mutation (SNP) | VAF 309/682 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs780864158; called by muse, mutect2, varscan2
- SH3BP5L | c.1130del p.G377Afs*152 | Frame Shift Del (DEL) | VAF 349/850 reads (41%) | catalogued as COSV63540198; called by mutect2, pindel, varscan2
- SH3RF1 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 25/509 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs930553580; called by muse, mutect2
- SHANK1 | c.3473T>C p.I1158T | Missense Mutation (SNP) | VAF 366/776 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1290658571, COSV53243751; called by muse, varscan2
- SHISA3 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 260/580 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.309); catalogued as rs755826430; called by muse, mutect2, varscan2
- SHOX2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 206/415 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.068); catalogued as rs762162461, COSV55829869; called by muse, mutect2, varscan2
- SHPK | c.949del p.V317Wfs*25 | Frame Shift Del (DEL) | VAF 221/574 reads (39%) | catalogued as COSV56649691; called by mutect2, pindel, varscan2
- SHPK | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 288/601 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs769295443; called by muse, mutect2, varscan2
- SHTN1 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373191933; called by muse, mutect2, varscan2
- SIGLEC14 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 350/737 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs1204790656, COSV55779002; called by muse, varscan2
- SIGLEC8 | c.561del p.M188* | Frame Shift Del (DEL) | VAF 248/523 reads (47%) | catalogued as rs1327914712; called by mutect2, varscan2
- SIM2 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 291/564 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1487720374; called by muse, mutect2, varscan2
- SKIV2L | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 307/636 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as rs1431710354; called by muse, mutect2, varscan2
- SLC12A5 | c.2364del p.L789Cfs*38 (on ENST00000454036 / NM_001134771.2; = p.L766Cfs*38 on NM_020708.5) | Frame Shift Del (DEL) | VAF 293/746 reads (39%) | catalogued as rs1568866957; called by mutect2, pindel, varscan2
- SLC13A5 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 299/645 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs558866003, COSV53422060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A5 | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 475/965 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69467230; called by muse, mutect2, varscan2
- SLC27A5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 234/508 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1365493197; called by muse, mutect2, varscan2
- SLC2A1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 245/519 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1425773776, COSV65287582; called by muse, mutect2, varscan2
- SLC37A3 | c.537del p.F179Lfs*18 | Frame Shift Del (DEL) | VAF 162/416 reads (39%) | catalogued as rs887174987; called by pindel, varscan2
- SLC39A7 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs943235103; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 126/270 reads (47%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC49A3 | c.660del p.T221Pfs*39 (on ENST00000404286 / NM_001294341.2; = p.T221Pfs*38 on NM_032219.4) | Frame Shift Del (DEL) | VAF 85/753 reads (11%) | catalogued as rs762838637; called by mutect2, pindel, varscan2
- SLC6A15 | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 164/316 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879925, COSV99880860; called by muse, mutect2, varscan2
- SLC7A1 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 197/459 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66329912; called by muse, mutect2, varscan2
- SLC7A4 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 303/592 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs781774672, COSV100298571; called by muse, mutect2, varscan2
- SLC7A9 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 171/392 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs939028046, CM010450, COSV50083062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 71/150 reads (47%) | catalogued as rs749004401; called by mutect2, varscan2
- SLCO3A1 | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 426/867 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.561); catalogued as rs1469034459; called by muse, mutect2, varscan2
- SLITRK5 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 214/414 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.233); catalogued as rs1449242517, COSV61521420; called by muse, mutect2, varscan2
- SLITRK5 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 27/840 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1383778657, COSV61524982; called by muse, mutect2
- SMARCA4 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 66/580 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs778890805, CM151153, COSV99065432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCB1 | c.214del p.T72Qfs*13 | Frame Shift Del (DEL) | VAF 183/482 reads (38%) | catalogued as COSV99574633; called by mutect2, pindel, varscan2
- SMC3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771561635, COSV62421150; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 364/720 reads (51%) | catalogued as rs747405143; called by mutect2, varscan2
- SNAI3 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 262/575 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752418440; called by muse, mutect2, varscan2
- SNRPA | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 44/748 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as COSV54681006, COSV99698857; called by muse, mutect2
- SOX11 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 246/488 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1436393730, COSV58984073; called by muse, mutect2, varscan2
- SOX3 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 398/398 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1374307659; called by muse, mutect2, varscan2
- SPAG17 | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs771461785; called by mutect2, pindel, varscan2
- SPATA31D3 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 207/1029 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs377006614; called by muse, mutect2, varscan2
- SPEG | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 255/525 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs759418830, COSV56663544; called by muse, mutect2, varscan2
- SPEN | c.6994C>T p.R2332C | Missense Mutation (SNP) | VAF 235/533 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs758740337, COSV65364636; called by muse, mutect2, varscan2
- SPEN | c.7464del p.I2489Sfs*10 | Frame Shift Del (DEL) | VAF 303/755 reads (40%) | catalogued as rs1557761571; called by mutect2, pindel, varscan2
- SPINT1 | c.1015C>A p.Q339K (on ENST00000344051 / NM_181642.3; = p.Q323K on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/484 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100689001; called by muse, mutect2
- SPON2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 359/761 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764898662; called by muse, mutect2, varscan2
- SPTA1 | c.4078C>A p.H1360N | Missense Mutation (SNP) | VAF 174/389 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63749094; called by muse, mutect2, varscan2
- SPTBN1 | c.5459G>A p.R1820H | Missense Mutation (SNP) | VAF 216/391 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs1317405298; called by muse, mutect2, varscan2
- SRCAP | c.5816G>A p.R1939H | Missense Mutation (SNP) | VAF 278/602 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs553945599; called by muse, varscan2
- SRM | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 18/467 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489497620; called by muse, mutect2
- STRN4 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 194/400 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs185426424; called by muse, mutect2, varscan2
- SULF1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 533/534 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769577350, COSV52673496, COSV52687237; called by muse, mutect2, varscan2
- SULF1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs768347353; called by muse, mutect2, varscan2
- SUPT16H | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs555039355; called by muse, mutect2, varscan2
- SUZ12 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 398/890 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV100496812; called by muse, varscan2
- SVIL | c.2239G>A p.A747T (on ENST00000355867 / NM_021738.3; = p.A353T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/344 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749968559; called by muse, mutect2, varscan2
- SVOPL | c.1244T>C p.V415A (on ENST00000419765; = p.V263A on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/365 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as rs113925266; called by muse, mutect2, varscan2
- SYT2 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 168/366 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as COSV66141806; called by muse, mutect2, varscan2
- SYT9 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 158/331 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1321732086, COSV100607353, COSV100607749; called by muse, mutect2, varscan2
- SYTL4 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 200/201 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs761721670, COSV99343094; called by muse, mutect2, varscan2
- TAF1B | c.1339del p.R447Efs*5 | Frame Shift Del (DEL) | VAF 87/224 reads (39%) | catalogued as COSV55157336; called by mutect2, pindel, varscan2
- TAF1L | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 241/589 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs371427336; called by muse, mutect2, varscan2
- TANK | c.1234del p.D412Ifs*27 | Frame Shift Del (DEL) | VAF 129/339 reads (38%) | catalogued as COSV52043878; called by mutect2, pindel, varscan2
- TAS2R1 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV66779306; called by muse, mutect2
- TBC1D16 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 204/407 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs374603858; called by muse, mutect2, varscan2
- TBC1D4 | c.2423T>C p.L808P | Missense Mutation (SNP) | VAF 135/261 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV66487541; called by muse, mutect2, varscan2
- TBX15 | c.994G>A p.E332K (on ENST00000369429 / NM_001330677.2; = p.E226K on NM_152380.3) | Missense Mutation (SNP) | VAF 29/423 reads (7%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.915); catalogued as rs1225498534, COSV52869563; called by muse, mutect2
- TBX3 | c.1960A>C p.S654R (on ENST00000257566 / NM_016569.4; = p.S634R on NM_005996.4) | Missense Mutation (SNP) | VAF 470/982 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1405449761; called by muse, mutect2, varscan2
- TBX3 | c.1048G>A p.A350T (on ENST00000257566 / NM_016569.4; = p.A330T on NM_005996.4) | Missense Mutation (SNP) | VAF 261/501 reads (52%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.65); catalogued as rs773465537, COSV57471123; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 298/685 reads (44%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TCF19 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 453/967 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs368077121, COSV52562965; called by muse, mutect2, varscan2
- TDRD15 | c.1697dup p.L566Ffs*5 | Frame Shift Ins (INS) | VAF 29/79 reads (37%) | catalogued as rs777153730; called by mutect2, pindel, varscan2
- TDRD6 | c.4672G>A p.V1558I | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs370070057; called by muse, mutect2, varscan2
- TECPR2 | c.3796G>T p.G1266W | Missense Mutation (SNP) | VAF 200/385 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63969028; called by muse, mutect2, varscan2
- TENM2 | c.2638C>T p.R880W (on ENST00000518659 / NM_001122679.2; = p.R648W on NM_001080428.3) | Missense Mutation (SNP) | VAF 204/455 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs748990955, COSV69133491; called by muse, mutect2, varscan2
- TEP1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 180/367 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1490977962, COSV52989798; called by muse, mutect2, varscan2
- TEX35 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 189/424 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.017); catalogued as rs776732666; called by muse, mutect2, varscan2
- TFF3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 61/638 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52295226; called by muse, mutect2
- TGM1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 279/594 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs777960926; called by muse, mutect2, varscan2
- THAP6 | c.320del p.N107Tfs*38 | Frame Shift Del (DEL) | VAF 100/240 reads (42%) | catalogued as rs1334718216; called by mutect2, pindel, varscan2
- THEMIS2 | c.1652dup p.P552Tfs*5 | Frame Shift Ins (INS) | VAF 153/416 reads (37%) | catalogued as rs750840849; called by mutect2, varscan2
- TKFC | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 179/429 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs1399928141; called by muse, mutect2, varscan2
- TM2D1 | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1391895632; called by muse, mutect2
- TMEM132B | c.1817T>C p.M606T | Missense Mutation (SNP) | VAF 57/522 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs956401315; called by muse, mutect2, varscan2
- TMEM132E | c.1804G>A p.A602T (on ENST00000321639; = p.A692T on NM_001304438.2) | Missense Mutation (SNP) | VAF 312/683 reads (46%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.453); catalogued as rs566317380; called by muse, mutect2, varscan2
- TMEM160 | c.401del p.G134Afs*75 | Frame Shift Del (DEL) | VAF 446/1118 reads (40%) | catalogued as rs954767051; called by mutect2, pindel, varscan2
- TMEM171 | c.918A>C p.E306D | Missense Mutation (SNP) | VAF 170/358 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as rs770749202; called by muse, mutect2, varscan2
- TMEM184A | c.219G>A p.Q73= | Splice Region (SNP) | VAF 17/368 reads (5%) | catalogued as rs1270901641; called by muse, mutect2
- TMEM200A | c.1293G>C p.M431I | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV51648640, COSV51660625; called by muse, mutect2, varscan2
- TMEM245 | c.1432del p.L478Yfs*3 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as COSV65823226; called by mutect2, pindel, varscan2
- TMEM53 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 314/637 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs371389325, COSV62408153; called by muse, mutect2, varscan2
- TMEM8B | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 296/593 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs917595034; called by muse, mutect2, varscan2
- TMPRSS4 | c.1196A>G p.H399R | Missense Mutation (SNP) | VAF 227/487 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV71109925; called by muse, mutect2, varscan2
- TMTC1 | c.1500G>T p.K500N (on ENST00000539277 / NM_001193451.2; = p.K392N on NM_175861.3) | Missense Mutation (SNP) | VAF 159/301 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.068); catalogued as COSV55490418; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 182/370 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771893296, COSV100835734; called by muse, mutect2, varscan2
- TP53BP1 | c.4567T>C p.Y1523H | Missense Mutation (SNP) | VAF 191/421 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV99780091; called by muse, mutect2, varscan2
- TRDN | c.996del p.E333Kfs*31 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV62135341; called by mutect2, pindel, varscan2
- TRERF1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 244/583 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs377409627; called by muse, mutect2, varscan2
- TRHDE | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1194627825; called by muse, varscan2
- TRIM46 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 366/749 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462888414, COSV58111362; called by muse, mutect2, varscan2
- TRIM49 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 109/286 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as COSV61670590; called by muse, varscan2
- TRIP12 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 204/451 reads (45%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.768); catalogued as rs373429636; called by muse, mutect2, varscan2
- TRMT1 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 225/452 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55564703; called by muse, mutect2, varscan2
- TRPC1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.081); catalogued as rs1175152675, COSV99859200; called by muse, mutect2, varscan2
- TRPC3 | c.259C>T p.R87W (on ENST00000379645 / NM_001366479.2; = p.R14W on NM_003305.2) | Missense Mutation (SNP) | VAF 178/413 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as rs778212103; called by muse, mutect2, varscan2
- TRPC6 | c.1128del p.K376Nfs*3 | Frame Shift Del (DEL) | VAF 107/241 reads (44%) | catalogued as COSV60250864; called by mutect2, pindel, varscan2
- TRPM6 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs771270884; called by muse, mutect2, varscan2
- TRRAP | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 232/528 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62841933; called by muse, mutect2, varscan2
- TSC2 | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 250/526 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs397515266; ClinVar: benign; called by muse, mutect2, varscan2
- TSFM | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 95/167 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55744871; called by muse, mutect2, varscan2
- TSHZ3 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 178/389 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs749560411, COSV53678144; called by muse, mutect2, varscan2
- TSHZ3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 222/483 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs535604105, COSV53671428; called by muse, mutect2, varscan2
- TSHZ3 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 241/533 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1210168815, COSV53666665, COSV53678557; called by muse, mutect2, varscan2
- TSKU | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 270/538 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs139490620; called by muse, varscan2
- TSPAN14 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 219/404 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100540198; called by muse, mutect2, varscan2
- TSPAN17 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 252/458 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs775926076, COSV53779259; called by muse, mutect2, varscan2
- TSPAN19 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1301106757; called by muse, mutect2, varscan2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 250/593 reads (42%) | catalogued as rs747842861, COSV101181233; called by mutect2, pindel, varscan2
- TSSK1B | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 216/439 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573427120; called by muse, mutect2, varscan2
- TTC17 | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 101/243 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs991034736; called by muse, mutect2, varscan2
- TTC21A | c.2180G>C p.G727A | Missense Mutation (SNP) | VAF 245/482 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV57188983; called by muse, mutect2, varscan2
- TTC28 | c.6203C>T p.A2068V | Missense Mutation (SNP) | VAF 246/527 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as rs956678270; called by muse, mutect2, varscan2
- TTLL10 | c.1001C>T p.A334V (on ENST00000379289 / NM_001130045.2; = p.A261V on NM_153254.3) | Missense Mutation (SNP) | VAF 308/669 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs763435422; called by muse, mutect2, varscan2
- TTLL12 | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 301/681 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs776233681; called by muse, mutect2, varscan2
- TTYH3 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 147/416 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757298103, COSV51860227; called by muse, mutect2, varscan2
- TUBB | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 476/962 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1473820852; called by muse, mutect2, varscan2
- TULP4 | c.2914C>T p.R972W | Missense Mutation (SNP) | VAF 302/662 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs762862451; called by mutect2, varscan2
- TXLNA | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 405/748 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs776145305; called by muse, mutect2, varscan2
- UBE3B | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 229/493 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs775845272; called by muse, mutect2, varscan2
- UBQLN4 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 58/626 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs867106433, COSV64145799; called by muse, mutect2
- UGP2 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1379499236, COSV61427845; called by mutect2, varscan2
- UGP2 | c.876C>T p.G292= | Splice Region (SNP) | VAF 13/277 reads (5%) | catalogued as rs1177583716, COSV61429167; called by muse, mutect2
- UGT1A9 | c.364del p.S122Qfs*12 | Frame Shift Del (DEL) | VAF 78/208 reads (38%) | catalogued as rs773627969; called by mutect2, pindel, varscan2
- ULK1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 203/419 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs370624303, COSV58857261; called by muse, mutect2, varscan2
- UNC50 | c.533del p.F178Sfs*7 | Frame Shift Del (DEL) | VAF 138/351 reads (39%) | catalogued as rs752307344; called by mutect2, pindel, varscan2
- URB1 | c.1985T>C p.M662T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs777107315; called by muse, mutect2, varscan2
- USP19 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 174/409 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as rs370990037; called by muse, mutect2, varscan2
- USP24 | c.2004A>G p.I668M | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs923909987; called by muse, mutect2
- USP28 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs550263885, COSV50155875; called by muse, mutect2
- USP35 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 343/654 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs974007395; called by muse, mutect2, varscan2
- USP4 | c.2813C>A p.S938Y | Missense Mutation (SNP) | VAF 32/578 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV55541465; called by muse, mutect2
- USP42 | c.3874C>T p.R1292C | Missense Mutation (SNP) | VAF 199/415 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs745441517, COSV60361427; called by muse, mutect2, varscan2
- USP45 | c.2108T>C p.V703A | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753729911; called by muse, mutect2, varscan2
- USP6 | c.3479C>A p.P1160Q | Missense Mutation (SNP) | VAF 114/315 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.408); catalogued as rs752498144; called by muse, mutect2, varscan2
- USPL1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 145/287 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs777354702, COSV99687223; called by muse, mutect2, varscan2
- UTF1 | c.749del p.P250Rfs*26 | Frame Shift Del (DEL) | VAF 153/341 reads (45%) | catalogued as rs898770563; called by mutect2, pindel, varscan2
- VARS2 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 430/908 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs762324080; called by muse, mutect2, varscan2
- VAX1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 131/246 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1420816659, COSV53327610; called by muse, mutect2, varscan2
- VWA1 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 314/639 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1299698179; called by muse, mutect2, varscan2
- VWA2 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 324/672 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1264494625; called by muse, mutect2, varscan2
- VWF | c.5989G>A p.A1997T | Missense Mutation (SNP) | VAF 51/419 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1158262683; called by muse, mutect2, varscan2
- WDR45 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100540124, COSV59876875; called by muse, mutect2
- WDR88 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 381/807 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs773116014; called by muse, mutect2, varscan2
- WFIKKN1 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 351/718 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs745474912, COSV50193058; called by muse, mutect2, varscan2
- WNK4 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 303/630 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as rs117902541; called by muse, mutect2, varscan2
- WWP2 | c.1296G>T p.W432C | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63126691; called by muse, mutect2, varscan2
- WWP2 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380761859; called by muse, mutect2, varscan2
- XCR1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 262/544 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs768217698, COSV58569474; called by muse, mutect2, varscan2
- XKR4 | c.155del p.G52Afs*225 | Frame Shift Del (DEL) | VAF 508/877 reads (58%) | catalogued as rs1450157201; called by pindel, varscan2
- XPC | c.2344G>A p.V782M | Missense Mutation (SNP) | VAF 297/632 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs370753746; called by muse, mutect2, varscan2
- XYLT2 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 286/577 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs761643084, COSV99191355; called by muse, mutect2, varscan2
- ZBTB40 | c.3655G>A p.V1219M | Missense Mutation (SNP) | VAF 218/444 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.297); catalogued as rs540888083; called by muse, mutect2, varscan2
- ZBTB7C | c.902del p.P301Hfs*38 | Frame Shift Del (DEL) | VAF 250/656 reads (38%) | catalogued as COSV59691239; called by mutect2, pindel, varscan2
- ZC3H3 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 226/945 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771433938, COSV99367922; called by muse, varscan2
- ZCCHC2 | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 111/239 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1333059553; called by muse, mutect2, varscan2
- ZDHHC5 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 220/601 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs779493997, COSV54707686; called by muse, mutect2, varscan2
- ZFP69B | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 138/307 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.265); catalogued as rs373622720; called by muse, mutect2, varscan2
- ZMYND12 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs773861975, COSV100999907; called by muse, mutect2, varscan2
- ZNF100 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111519833; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 117/285 reads (41%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF251 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 278/1103 reads (25%) | catalogued as rs377393106; called by muse, mutect2, varscan2
- ZNF296 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 506/1012 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV54319706; called by muse, mutect2, varscan2
- ZNF34 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 153/588 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as rs753031844; called by muse, varscan2
- ZNF420 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1487563804; called by muse, mutect2, varscan2
- ZNF438 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 276/542 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59196703; called by muse, mutect2, varscan2
- ZNF467 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 57/1025 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1432538901; called by muse, mutect2
- ZNF471 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 170/430 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs578040016; called by muse, mutect2
- ZNF484 | c.1129dup p.I377Nfs*9 | Frame Shift Ins (INS) | VAF 38/96 reads (40%) | catalogued as rs1481611472, COSV60257456; called by mutect2, varscan2
- ZNF584 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 198/442 reads (45%) | catalogued as rs746876189; called by muse, mutect2, varscan2
- ZNF587 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 36/271 reads (13%) | catalogued as rs201492279; called by muse, mutect2, varscan2
- ZNF653 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 384/811 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1232701148; called by muse, mutect2, varscan2
- ZNF675 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.632); catalogued as rs1405261145; called by muse, mutect2, varscan2
- ZNF676 | c.1822G>A p.V608I (on ENST00000650058; = p.V576I on NM_001001411.3) | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs532104019, COSV68094084, COSV68094186; called by muse, mutect2, varscan2
- ZNF696 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 390/1567 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV57524783; called by muse, mutect2, varscan2
- ZNF74 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 369/730 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199814477, COSV62621583; called by muse, mutect2, varscan2
- ZNF761 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs566316404; called by muse, mutect2, varscan2
- ZNF875 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1248069382; called by muse, mutect2, varscan2
- ZP1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 182/391 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs765567849; called by muse, mutect2, varscan2
- ABCA1 | c.6398del p.N2133Ifs*9 | Frame Shift Del (DEL) | VAF 120/280 reads (43%) | called by mutect2, pindel, varscan2
- ABCC3 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 351/781 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC4 | c.2648dup p.L883Ffs*46 | Frame Shift Ins (INS) | VAF 134/346 reads (39%) | called by mutect2, pindel, varscan2
1,633 further variants in this file (993 protein-altering or splice-affecting, 548 silent, 92 other) are not listed here.
